TCGA case TCGA-YU-A94I — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6b67920-f8e8-40fe-a5dd-aa0004d88a21

Demographics
Sex at birth: male; Country of residence at enrollment: Brazil; Age at index: 66 years; Year of birth: 1946; Vital status: Alive.

Diagnoses (1)
1. Yolk sac tumor: ICD-O-3 morphology code: 9071/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.7 years (24,349 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 536 days (1.5 years); Ajcc serum tumor markers: S0.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (6 entries)
- Days to follow up: 242 days; Disease response: Tumor Free.
- Days to follow up: 255 days; Disease response: Tumor Free.
- Days to follow up: 438 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 472 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 536 days (1.5 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -39: Alpha Fetoprotein 5972; Human Chorionic Gonadotropin 13.2.
- Day 55: Lactate Dehydrogenase 313; Alpha Fetoprotein 17.9; Human Chorionic Gonadotropin 0.2.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YU-A94I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 280 mg.
  Slide TCGA-YU-A94I-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 22; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-YU-A94I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YU-A94I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: No; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 5.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor; Histologic diagnosis percent: 95.
- Primary pathology, Pre orchi serum marker info: Pre orchi hcg: 13.2; Pre orchi afp: 5972.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 313; Post orchi hcg: 0.2; Post orchi afp: 17.9.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 536 days; disease-specific survival: no event (censored), 536 days; disease-free interval: no event (censored), 536 days; progression-free interval: no event (censored), 536 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YU-A94I-01A-11D-A434-01): tumor purity 0.88, ploidy 2.69, whole-genome doublings 1.
